Gene-level copy-number profile of tumor specimen TCGA-VR-A8EX-01A from TCGA case TCGA-VR-A8EX, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.6 years (23,226 days).
Specimen TCGA-VR-A8EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.687726f1-1a50-4b67-a241-3c3fb9ebd7d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8EX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5ff38ed-fa37-494e-bce8-1a12ab73944e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 177; copy number 2: 7,513; copy number 3: 17,212; copy number 4: 23,352; copy number 5: 9,574; copy number 6: 853; copy number 7: 222; copy number 8: 200; copy number 9: 217; copy number 10: 115; copy number 11: 13; copy number 12: 13; copy number 13: 15; copy number 14: 73; copy number 15: 20; copy number 16: 3; copy number 17: 72; copy number 20: 12; copy number 21: 16; copy number 23: 6; copy number 24: 35; copy number 25: 12; copy number 26: 12; copy number 27: 6; copy number 28: 2; copy number 29: 4; copy number 32: 4; copy number 33: 18; copy number 48: 18; copy number 50: 4; copy number 55: 7; copy number 61: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8EX-01A-11D-A36I-01): tumor purity 0.48, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–5): AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 702 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,991,276–41,043,890, 78 genes, copy number 9 (broad region; genes not listed).
- chr3:11,745–54,346, 2 genes, copy number 16: LINC01986, AC066595.1.
- chr3:156,671,862–158,571,066, 33 genes, copy number 14: TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4, LEKR1, KLF3P2, AC117392.1, RN7SKP177, LINC00880, LINC02029, LINC00881, CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146, AC092944.1, AC092944.2, AC092944.3, VEPH1, PTX3, SLC66A1L, AC084212.1, AC079943.2, RN7SKP46, AC079943.1, SHOX2, RSRC1, AC074276.1, AC074276.2, AC106707.2, AC106707.1.
- chr3:177,010,719–182,368,256, 96 genes, copy number 10–15 (broad region; genes not listed).
- chr7:54,676,217–55,955,239, 36 genes, copy number 9 (within-gene range 6–9): AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713.
- chr8:39,522,976–42,844,876, 68 genes, copy number 9–23 (within-gene range 7–23) (broad region; genes not listed).
- chr8:99,873,200–100,559,784, 19 genes, copy number 11–17: COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62.
- chr8:125,430,358–128,564,679, 47 genes, copy number 12–17 (within-gene range 7–17): TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr11:26,559,032–26,572,263, 1 gene, copy number 16 (within-gene range 8–16): MUC15.
- chr11:26,994,112–27,722,058, 14 genes, copy number 13–20 (within-gene range 3–20): FIBIN, BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF.
- chr11:68,683,779–71,423,423, 65 genes, copy number 24–33 (within-gene range 5–33) (broad region; genes not listed).
- chr12:30,086,342–30,130,590, 1 gene, copy number 13: AC023511.3.
- chr14:21,918,188–21,966,061, 6 genes, copy number 27: TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3.
- chr14:30,874,514–31,457,506, 18 genes, copy number 9–25: COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2.
- chr14:35,362,232–38,371,338, 60 genes, copy number 21–61: AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1.
- chr17:33,529,787–33,541,339, 2 genes, copy number 9: AA06, AC011824.3.
- chr17:39,566,915–39,877,896, 16 genes, copy number 9: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr17:40,597,113–40,721,932, 8 genes, copy number 10: AC004585.2, SMARCE1, AC073508.2, AC073508.3, KRT222, AC073508.1, KRT24, KRT223P.
- chr17:44,034,328–45,109,016, 60 genes, copy number 9: LSM12, G6PC3, HDAC5, AC023855.1, RNU6-131P, HROB, ASB16, ASB16-AS1, TMUB2, ATXN7L3, AC004596.1, UBTF, MIR6782, AC003102.1, SHC1P2, SLC4A1, AC003043.2, RN7SL507P, RUNDC3A-AS1, U3, RNU6-453P, RUNDC3A, SLC25A39, AC003043.1, GRN, FAM171A2, RPL7L1P5, ITGA2B, GPATCH8, RN7SL258P, AC103703.1, FZD2, AC091152.3, SMCO4P1, LINC01180, MEIOC, CCDC43, AC091152.2, AC091152.4, DBF4B, RN7SL819P, AC091152.1, ADAM11, AC005180.2, AC005180.1, GJC1, HIGD1B, EFTUD2, RN7SL405P, CCDC103, FAM187A, GFAP, KIF18B, MIR6783, AC015936.1, NMT1, C1QL1, AC015936.2, DCAKD, Y_RNA.
- chr17:45,114,367–45,114,433, 1 gene, copy number 9: MIR6784.
- chr19:36,528,318–38,332,076, 71 genes, copy number 10–14 (within-gene range 5–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 177. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
